Somatic mutation profile of tumor specimen TCGA-C5-A1MN-01A (aliquot TCGA-C5-A1MN-01A-11D-A14W-08) from TCGA case TCGA-C5-A1MN, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 42.4 years (15,499 days).
Specimen TCGA-C5-A1MN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b39607e3-013f-4fed-8464-99c254f8ce6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1MN-10A (Blood Derived Normal), aliquot TCGA-C5-A1MN-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a2595b1-bc0c-4ab2-8c7a-8f95f492dea6

The open-access MAF lists 162 somatic variants for this specimen: 119 protein-altering or splice-affecting, 43 silent.
By variant classification: Missense Mutation 105, Silent 43, Nonsense Mutation 10, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.5131A>T p.K1711* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as rs794727342, COSV56467964, COSV56489878; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHI1 | c.3151G>C p.D1051H | Missense Mutation (SNP) | VAF 85/243 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.557); catalogued as COSV55628900; called by muse, mutect2, varscan2
- ANAPC1 | c.2591C>T p.P864L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as rs201476913; called by muse, mutect2, varscan2
- AR | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.265); catalogued as rs1021234843, COSV101018827; called by muse, mutect2, varscan2
- ARID4B | c.1273G>C p.E425Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as COSV51600823; called by muse, mutect2, varscan2
- B2M | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 33/98 reads (34%) | catalogued as COSV62563605; called by muse, mutect2, varscan2
- BDP1 | c.4174G>A p.E1392K | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV62429799, COSV62434599; called by muse, mutect2, varscan2
- CCDC93 | c.1329G>C p.L443F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs577755174; called by muse, mutect2, varscan2
- CDC25B | c.1169G>A p.R390Q (on ENST00000245960 / NM_021873.3; = p.R376Q on NM_004358.4) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as rs770335566, COSV99847470; called by muse, mutect2, varscan2
- CELSR2 | c.7429G>A p.G2477S | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs762634072, COSV54769058; called by muse, mutect2, varscan2
- CNTNAP2 | c.1343C>G p.S448C | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV62195484; called by muse, mutect2, varscan2
- CTNNA2 | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV58143442, COSV58154065; called by muse, mutect2, varscan2
- DCAF6 | c.1258C>G p.Q420E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.022); catalogued as COSV56575308; called by muse, mutect2, varscan2
- DENND5B | c.3715G>A p.A1239T | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100171432, COSV60905604; called by muse, mutect2, varscan2
- DNAJC28 | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV58721682; called by muse, mutect2, varscan2
- ELMO3 | c.322G>A p.D108N (on ENST00000652269; = p.D55N on NM_024712.5) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs750988812; called by muse, varscan2
- FAM120A | c.1220C>T p.T407M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs543764284, COSV99464711; called by mutect2, varscan2
- FAM184A | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.705); catalogued as COSV58854196; called by muse, mutect2, varscan2
- HECW1 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as COSV67826950; called by muse, mutect2, varscan2
- IGLV1-44 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 25/94 reads (27%) | catalogued as rs371336477; called by muse, mutect2, varscan2
- IL36B | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.119); catalogued as COSV52087632, COSV52089438; called by muse, mutect2, varscan2
- INVS | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1228736160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JAK2 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 91/177 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV67678408; called by muse, mutect2, varscan2
- KCNH6 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as rs1340805306; called by muse, mutect2, varscan2
- MARCHF6 | c.1979G>A p.R660H | Missense Mutation (SNP) | VAF 121/142 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1408481910, COSV56882324, COSV56882852; called by muse, mutect2, varscan2
- MMP8 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1294178354; called by muse, mutect2
- MNS1 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV53068940; called by muse, mutect2, varscan2
- NACC1 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as rs1399127336; called by muse, mutect2
- NAPEPLD | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100439722, COSV100439879; called by muse, mutect2, varscan2
- NCAM2 | c.907C>G p.H303D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV53085021; called by muse, mutect2, varscan2
- NOTCH1 | c.4461G>C p.W1487C | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53031789, COSV53078816; called by muse, mutect2, varscan2
- NOTCH1 | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.511); catalogued as rs587778569, COSV53065797, COSV99484075; ClinVar: not provided / uncertain significance; called by muse, mutect2
- PHKA2 | c.2672C>T p.T891M | Missense Mutation (SNP) | VAF 94/242 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1403524475, COSV101177005; called by muse, mutect2, varscan2
- PIK3R4 | c.3835G>A p.V1279I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1456609197; called by muse, mutect2, varscan2
- PTPN13 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV100365341; called by muse, mutect2, varscan2
- RHOT2 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1429906554, COSV53466120; called by muse, mutect2, varscan2
- RNF213 | c.6526C>G p.Q2176E | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV100300082, COSV100301691; called by muse, varscan2
- RYR2 | c.5018C>T p.A1673V | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63682767; called by muse, mutect2, varscan2
- SIRPD | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV67546424; called by muse, mutect2, varscan2
- SLC25A3 | c.996C>G p.I332M (on ENST00000228318 / NM_005888.3; = p.I331M on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs771553727; called by muse, varscan2
- SLC37A2 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs201149895; called by muse, mutect2, varscan2
- STXBP6 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV60592845; called by muse, mutect2, varscan2
- SUN5 | c.1069G>A p.V357M | Missense Mutation (SNP) | VAF 121/206 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs188077154; called by muse, mutect2, varscan2
- TCTE1 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV65256016; called by muse, mutect2, varscan2
- TFAP2A | c.746C>T p.S249L (on ENST00000482890; = p.S241L on NM_001032280.3) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as CM110104, CM113567, COSV60237165; called by muse, mutect2
- TINF2 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs780611874; called by muse, mutect2, varscan2
- TRPC7 | c.404A>G p.Q135R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1341223606; called by muse, mutect2, varscan2
- TTLL1 | c.331C>G p.P111A | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334837694; called by muse, mutect2, varscan2
- TTN | c.102361C>T p.R34121* (on ENST00000591111; = p.R26697* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as rs1477669354, COSV60043419; called by muse, mutect2, varscan2
- WDR3 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 39/90 reads (43%) | catalogued as rs1235254790; called by muse, mutect2, varscan2
- ZNF100 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as rs752413588; called by muse, mutect2, varscan2
- ZNF143 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs768865975; called by muse, mutect2, varscan2
- ZNF219 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53882221; called by muse, mutect2, varscan2
- ADGRG4 | c.3343A>G p.R1115G | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ANKS6 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ASCC3 | c.141G>A p.W47* | Nonsense Mutation (SNP) | VAF 46/146 reads (32%) | called by muse, mutect2, varscan2
- ATMIN | c.1678G>C p.E560Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ATRNL1 | c.3992C>T p.S1331L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- C1QL1 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CAPN15 | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCPG1 | c.2192del p.R731Nfs*19 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- CDC42EP3 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK12 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- CES3 | c.686C>G p.S229C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP57 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CIC | c.3268C>A p.P1090T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- CLCN5 | c.2063del p.F688Sfs*3 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, varscan2
- CLCN5 | c.2063T>C p.F688S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by mutect2, varscan2
- COL21A1 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- CPB2 | c.731T>G p.F244C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- DST | c.10369G>A p.E3457K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- EIF5 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- EPHB2 | c.1393G>T p.V465L | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ESRP2 | c.946C>T p.Q316* (on ENST00000565858 / NM_001365264.1; = p.Q306* on NM_024939.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- FAT2 | c.12174C>G p.F4058L | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBN1 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GANAB | c.1559G>A p.W520* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- GPR15 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- GPR61 | c.1283A>G p.Q428R | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSPG2 | c.3169G>T p.V1057L | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ICAM2 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- ITGA4 | c.1364C>A p.S455Y | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KATNIP | c.2742C>G p.I914M | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KIF3B | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- LPAR1 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAGEB6B | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MFF | c.1022G>C p.R341P | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYCBP2 | c.361C>G p.L121V (on ENST00000357337; = p.L159V on NM_015057.5) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- NOL4 | c.1837G>T p.V613F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NOTCH1 | c.4224G>T p.E1408D | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.29); PolyPhen benign (0.02); called by muse, mutect2
- NOTCH1 | c.3544G>C p.E1182Q | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NPR1 | c.2250G>A p.E750= | Splice Region (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- NUDT9 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OLA1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PDE3A | c.981G>T p.W327C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PIP4P2 | c.538dup p.I180Nfs*6 | Frame Shift Ins (INS) | VAF 24/78 reads (31%) | called by mutect2, varscan2
- PKN3 | c.1296C>G p.I432M | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- PPIAL4A | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRAMEF4 | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 87/383 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- PUM1 | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); called by muse, varscan2
- RAPH1 | c.3175G>T p.D1059Y | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- RASAL3 | c.3025G>A p.D1009N | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTCB | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SGPL1 | c.1679A>G p.Q560R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SLC25A3 | c.1058C>G p.S353C (on ENST00000228318 / NM_005888.3; = p.S352C on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- SOBP | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SP3 | c.2324C>T p.S775F | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SPEG | c.8769G>T p.E2923D | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SSX5 | c.512G>T p.R171I (on ENST00000347757 / NM_175723.1; = p.R212I on NM_021015.4) | Missense Mutation (SNP) | VAF 57/327 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- STXBP4 | c.391G>T p.G131* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- TARS3 | c.1001G>A p.G334D | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENM4 | c.5966T>C p.I1989T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TRPM6 | c.5681T>A p.I1894N | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TTLL1 | c.447C>G p.F149L | Missense Mutation (SNP) | VAF 113/376 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- TTN | c.37420C>A p.Q12474K (on ENST00000591111; = p.Q5050K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TUT7 | c.4288G>A p.E1430K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- USP1 | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF711 | c.1206G>A p.M402I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ABCA13 | c.778C>T p.L260= | Silent (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- ABCD3 | c.1821C>A p.G607= | Silent (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- ACTA1 | c.606C>T p.F202= | Silent (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- ADAM11 | c.819C>T p.A273= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs140421831; called by muse, mutect2, varscan2
- BAHCC1 | c.6459C>G p.L2153= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100311242; called by muse, mutect2, varscan2
- BRINP2 | c.537A>T p.I179= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV64178941; called by muse, mutect2, varscan2
- CAPN10 | c.1428C>T p.D476= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as rs754583407, COSV54380893; called by muse, mutect2, varscan2
- CDKL5 | c.1311C>T p.N437= | Silent (SNP) | VAF 67/201 reads (33%) | called by muse, mutect2, varscan2
- COPE | c.912C>T p.Y304= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs377486646; called by muse, mutect2, varscan2
- CRYGB | c.243C>T p.L81= | Silent (SNP) | VAF 52/117 reads (44%) | called by muse, mutect2, varscan2
- DLGAP1 | c.1515C>T p.D505= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs369261142; called by muse, mutect2, varscan2
- DOK3 | c.54C>A p.V18= | Silent (SNP) | VAF 25/42 reads (60%) | called by muse, mutect2, varscan2
- ESRP2 | c.945G>T p.L315= (on ENST00000565858 / NM_001365264.1; = p.L305= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs758240299; called by muse, mutect2, varscan2
- GALNTL6 | c.1590C>G p.L530= | Silent (SNP) | VAF 45/70 reads (64%) | called by muse, mutect2, varscan2
- GK | c.456G>C p.V152= | Silent (SNP) | VAF 53/110 reads (48%) | called by muse, mutect2, varscan2
- GLYAT | c.582G>A p.Q194= | Silent (SNP) | VAF 33/88 reads (38%) | called by muse, mutect2, varscan2
- HEATR1 | c.6135G>C p.L2045= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs759724118; called by muse, mutect2, varscan2
- HEXB | c.183C>T p.L61= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs1163328393; called by muse, varscan2
- KBTBD3 | c.1782C>T p.C594= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV101595724; called by muse, mutect2, varscan2
- KCNK9 | c.699G>A p.T233= | Silent (SNP) | VAF 25/32 reads (78%) | catalogued as rs201576708, COSV57288026; called by muse, mutect2, varscan2
- KIAA0319 | c.2121C>T p.L707= | Silent (SNP) | VAF 34/47 reads (72%) | catalogued as COSV65498628; called by muse, mutect2, varscan2
- KPRP | c.357C>T p.Y119= | Silent (SNP) | VAF 119/278 reads (43%) | catalogued as rs781161487, COSV64221316; called by muse, mutect2, varscan2
- KRT34 | c.633G>C p.L211= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs773299359; called by muse, mutect2, varscan2
- KRT38 | c.510C>T p.A170= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs186989114; called by muse, mutect2, varscan2
- LCAT | c.861C>T p.H287= | Silent (SNP) | VAF 49/114 reads (43%) | catalogued as rs767628388; called by muse, mutect2, varscan2
- MINDY2 | c.885G>A p.L295= | Silent (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- MOCOS | c.426G>C p.G142= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.222C>T p.L74= | Silent (SNP) | VAF 39/227 reads (17%) | catalogued as COSV57107186; called by muse, mutect2, varscan2
- NT5C1B | c.714G>A p.T238= (on ENST00000359846 / NM_001199086.2; = p.T178= on NM_033253.4) | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2
- PCNX1 | c.3483T>C p.L1161= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV99454510; called by muse, mutect2, varscan2
- PDS5A | c.582C>T p.I194= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- PHF14 | c.1068G>A p.E356= | Silent (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- PRPF8 | c.6849C>T p.F2283= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs1225760329, COSV100025372; called by muse, mutect2, varscan2
- PTPRN | c.2910G>A p.V970= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs1412370363; called by muse, mutect2, varscan2
- PTPRN | c.1422C>T p.I474= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs778155767, COSV55348033; called by muse, mutect2, varscan2
- RFC2 | c.480C>T p.I160= (on ENST00000055077 / NM_181471.3; = p.I126= on NM_002914.4) | Silent (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- RNF213 | c.6363C>T p.F2121= | Silent (SNP) | VAF 108/244 reads (44%) | called by muse, varscan2
- SEC14L4 | c.450G>C p.L150= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs199986939; called by muse, mutect2, varscan2
- SEMA5A | c.1746C>T p.C582= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs376581828; called by muse, mutect2, varscan2
- SH2D4A | c.1062C>G p.L354= | Silent (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- STAMBP | c.984C>T p.L328= | Silent (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- VWA3B | c.3726C>T p.P1242= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs753353583; called by muse, varscan2
- ZNF646 | c.3432G>A p.P1144= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs1284532416; called by muse, mutect2, varscan2
